Surgical pathology report (de-identified scan), TCGA case TCGA-34-2608, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-34-2608-01A (Primary Tumor).

[page 1 of 3]
CLINICAL HISTORY

The patient is a [REDACTED] year-old male with history of upper lobe mass on chest X-ray. CT guided biopsy shows invasive squamous cell carcinoma, well differentiation.

PRE OP DIAGNOSIS: Left upper lobe mass.

POST OP DIAGNOSIS: Same.

PROCEDURE: Left upper lobe, lobectomy.

AMENDED-CORRECTED REPORT

This report is being amended to reflect evidence of vascular and pleural invasion, with a resulting change in the tumor stage.

This is an Amended/Corrected report and reflects a change to either the diagnosis and/or report. All previous copies of this report should be destroyed. The Medical Records Department has likewise been given a copy of this corrected report, and we have made every effort to remove old copies of the previous pathology report from the patient record.

FINAL DIAGNOSIS**SUMMARY STATEMENT**

The patient is an [REDACTED] man with a 2.4 cm moderately differentiated invasive squamous cell carcinoma of the left upper lobe. Vascular and bronchial margins are free and the tumor involves the visceral but not the parietal pleura. Hilar lymph nodes, lymph node near lingular artery, left upper lobe segmental lymph node and left level 5 lymph node are all negative for tumor. Angiolymphatic invasion is seen. There is a mild host lymphocytic response. The TNM staging is T2N0MX, stage 1B. The non-neoplastic lung shows emphysematous changes.

PART 1: LYMPH NODE, NEAR LINGUAL ARTERY, EXCISION

- A. FRAGMENTS OF ANTHRACOTIC LYMPH NODE.
- B. NO TUMOR SEEN.

PART 2: LYMPH NODE, SEGMENTAL LYMPH NODE, EXCISION

- A. FRAGMENTS OF ANTHRACOTIC LYMPH NODE.
- B. NO TUMOR SEEN.

PART 3: LYMPH NODE, LEFT LEVEL FIVE, EXCISION

- A. ONE BENIGN ANTHRACOTIC LYMPH NODE.
- B. NO TUMOR SEEN.

PART 4: LEFT UPPER LOBE, LOBECTOMY

- A. MODERATELY DIFFERENTIATED INVASIVE SQUAMOUS CELL CARCINOMA (2.4 CM).
- B. VASCULAR MARGINS AND BRONCHIAL MARGINS FREE OF TUMOR.
- C. VISCERAL PLEURA INVOLVED BY TUMOR.
- D. ANGIOLYMPHATIC INVASION SEEN.
- E. TWO HILAR LYMPH NODES NEGATIVE FOR TUMOR.
- F. MILD HOST LYMPHOCYTIC RESPONSE.
- G. MILD EMPHYSEMATOUS CHANGES.
- H. TNM STAGING T2N0MX, STAGE 1B.

mp

COMMENT

[page 2 of 3]
COMMENT

{Not Entered}

GROSS DESCRIPTION

The specimen is received in four parts.

Part 1 is labeled "lymph node near lingular artery". Received five anthracotic irregular pieces of tissue ranging in size from 0.4 x 0.2 cm to 1.1 x 0.8 x 0.2 cm. All five pieces are submitted entirely in a single cassette labeled 1A.

Part 2 is labeled "left upper lobe, segmental lymph node". Received in saline is a single anthracotic irregular piece of tissue measuring 1.2 x 0.9 x 0.3 cm. Submitted entirely in a cassette labeled 2A.

Part 3 is labeled "left level 5 lymph node in blood stained fluid". It consists of a single piece of tissue measuring 6.0 x 0.6 x 0.2 cm. Submitted entirely in a cassette labeled 3A.

Part 4 is labeled "left upper lobe". It consists of a grayish-pink, anthracotic lobe of lung measuring 15.0 x 11.0 x 0.9 cm. There is puckering of the pleural surface corresponding to which there is a firm mass on palpation. The bronchial (stapled) and vascular margin is identified. There is no additional parenchyma stapled margin. The specimen is inked and serially sectioned and shows a grayish white tumor measuring 2.4 x 2.1 x 0.4 cm. The tumor seems to be close to the pleural surface but does not extend up to the pleural surface grossly. The lung parenchyma appears normal. Sections are submitted as follows:

4A - hilar lymph nodes

4B - vascular margin

4C - bronchial margin

4D - parenchyma adjacent to the bronchial margin.

4E through 4H - tumor (sections including tumor with pleura and adjacent non-neoplastic lung)

4I - non-neoplastic lung

MICROSCOPIC DESCRIPTION

SYNOPTIC PRIMARY LUNG TUMORS

A.Location: 5

1. RUL

3. RLL

5. LUL

2. RML

4. LLL

6. Bronchus intermedius

B.Procedure: 2

1.Wedge/Segmental

3. Bilobectomy

2.Lobectomy

4. Pneumonectomy

C.Size of tumor (maximum dimension): 2.4 cm.

D.Satellite nodules: 2

1. yes

2. no

E.Type: 1

1.Invasive squamous carcinoma

9. Sarcomatoid carcinoma

2. Basaloid squamous carcinoma

10. Blastoma

3.Invasive adenocarcinoma

11. Fetal type adenocarcinoma

4.Bronchioloalveolar carcinoma, nonmucinous type

12. Oat cell carcinoma

5.Bronchioloalveolar carcinoma, mucinous type

13. Carcinoid

6.Large cell carcinoma

14. Atypical carcinoid

7.Clear cell carcinoma

15. Sarcoma

8.Giant cell carcinoma

16. Other

F.Grade: 2

1. well

2. moderate

3. poor/undifferentiated

[page 3 of 3]
G.Bronchogenic (versus parenchymal) origin: 2

1. yes 2. no

H.Visceral pleural invasion: 1

1. yes 2. no

I.Parietal pleural invasion:2

1. yes 2. no

J. Chest wall invasion: 2

1. yes 2. no

K.Angiolymphatic invasion: 1

1. yes 2. no

L.Surgical margins involved: 2

1. yes 2. no

M.Inflammatory (desmoplastic) reaction: 1

1. mild 2. moderate 3. severe

N.Hilar lymph node involvement: 2

1. yes 2. no

O.If hilar lymph nodes involved, # positive / # examined = N /A

P.Mediastinal nodes involved: 2

1. yes 2. no 3. not applicable

Q.Mediastinal node group(s) involved: N/A

1. Level 4R	4. Level 7R	7. Level 4L	10. Level 7L
2. Level 5R	5. Level 9R	8. Level 5L	11. Level 9L
3. Level 6R	6. Level 10R	9. Level 6L	12. Level 10L

R.Underlying disease(s): 1

1. Emphysema	3. Tumorlets	5. Asthma
2. Bronchiectasis	4. Smokers bronchiolitis	6. Parenchymal scar

S. TNM Stage: T 2 N 0 M X

INTRAOPERATIVE DIAGNOSIS

{Not Entered}

Source: NCI Genomic Data Commons file a700be50-ed97-4615-937b-67c046791fa5 (TCGA-34-2608.18C043AB-DF83-40BF-BAFC-E33AED1EBDEA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).